CCDI case PBBVKF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5a0f7024-3233-46dc-8a71-c264cd895678

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.1 years (1,487 days).

Biospecimens (3 samples)
- Sample 0DI7SD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI7V0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DI7VH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
